Somatic mutation profile of tumor specimen TARGET-30-PATPYK-01A (aliquot TARGET-30-PATPYK-01A-01D) from TARGET case TARGET-30-PATPYK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.7 years (634 days).
Specimen TARGET-30-PATPYK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3940bbdd-6077-412b-ba02-1c9b8d261f86.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATPYK-10A (Blood Derived Normal), aliquot TARGET-30-PATPYK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be9f4c36-5633-4d14-adc2-b3496eb45db3

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- MET | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1318406399; called by muse, mutect2
- ANKRD30A | c.195C>T p.N65= (on ENST00000611781; = p.N9= on NM_052997.2) | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs754231282; called by muse, varscan2
- FMN1 | c.*5820G>A | 3'UTR (SNP) | VAF 91/190 reads (48%) | catalogued as COSV57924654; called by muse, mutect2, varscan2
